Somatic mutation profile of tumor specimen TCGA-50-7109-01A (aliquot TCGA-50-7109-01A-11D-2036-08) from TCGA case TCGA-50-7109, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 60.2 years (21,979 days).
Specimen TCGA-50-7109-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eefede70-b24c-4d61-a4c8-f2d7575f7a54.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-50-7109-11A (Solid Tissue Normal), aliquot TCGA-50-7109-11A-01D-2036-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cecda4e0-1f1d-4df9-8acd-88eac8c53c25

The open-access MAF lists 258 somatic variants for this specimen: 202 protein-altering or splice-affecting, 52 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 176, Silent 52, Nonsense Mutation 12, Splice Region 4, Frame Shift Del 4, Frame Shift Ins 3, Splice Site 2, Intron 2, RNA 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA1 | c.907G>A p.A303T | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.248); catalogued as COSV66067159; called by muse, mutect2, varscan2
- ADAM7 | c.929G>T p.C310F | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51541070; called by muse, mutect2, varscan2
- ADAMTS12 | c.4215C>A p.C1405* | Nonsense Mutation (SNP) | VAF 72/176 reads (41%) | catalogued as COSV61265024; called by muse, mutect2, varscan2
- AGA | c.742G>T p.D248Y | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750546930, COSV52806512; called by muse, mutect2, varscan2
- AK5 | c.767A>G p.K256R (on ENST00000354567 / NM_174858.3; = p.K230R on NM_012093.4) | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.999); catalogued as COSV60974316; called by muse, mutect2, varscan2
- AMZ1 | c.170C>T p.T57I | Missense Mutation (SNP) | VAF 41/169 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.168); catalogued as COSV56687341; called by muse, mutect2, varscan2
- ARL13B | c.887A>T p.E296V (on ENST00000394222 / NM_001174150.2; = p.E189V on NM_144996.4) | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV57398802; called by muse, mutect2
- ARMC3 | c.2400G>T p.L800F | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53062464; called by muse, mutect2
- ASB2 | c.907A>G p.R303G | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as COSV60112345; called by muse, mutect2, varscan2
- ATP10B | c.3473C>A p.P1158H | Missense Mutation (SNP) | VAF 45/152 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59154398; called by muse, mutect2, varscan2
- BANP | c.1003C>T p.R335W (on ENST00000286122; = p.R304W on NM_017869.4) | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53738615; called by muse, mutect2, varscan2
- BDNF | c.24G>A p.M8I | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.914); catalogued as COSV59235701; called by muse, mutect2, varscan2
- BPTF | c.8285A>T p.D2762V | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as COSV58838658; called by muse, mutect2, varscan2
- CACNA2D1 | c.3292A>T p.S1098C (on ENST00000356253 / NM_001366867.1; = p.S1086C on NM_000722.4) | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV62381283; called by muse, mutect2, varscan2
- CAVIN3 | c.367C>T p.H123Y | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as rs1272936119, COSV58269124; called by muse, mutect2
- CCKAR | c.333C>A p.S111R | Missense Mutation (SNP) | VAF 49/674 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.889); catalogued as COSV55161941; called by muse, mutect2
- CDC42BPA | c.2455G>T p.A819S | Missense Mutation (SNP) | VAF 14/171 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.348); catalogued as rs924052956, COSV62012562; called by muse, mutect2
- CDC42BPA | c.640C>G p.H214D | Missense Mutation (SNP) | VAF 86/155 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62009680, COSV62012578; called by muse, mutect2, varscan2
- CEACAM5 | c.604C>A p.L202I | Missense Mutation (SNP) | VAF 92/172 reads (53%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.969); catalogued as COSV55751744, COSV55752568; called by muse, mutect2, varscan2
- CEP135 | c.1819G>T p.E607* | Nonsense Mutation (SNP) | VAF 7/77 reads (9%) | catalogued as COSV57259844, COSV57260649; called by muse, mutect2, varscan2
- CFAP52 | c.122A>T p.Y41F | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as rs1313058909, COSV55345475; called by muse, mutect2
- CFAP52 | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.539); catalogued as COSV55345492; called by muse, mutect2
- CFAP65 | c.1908C>A p.F636L | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as COSV58562000; called by muse, mutect2, varscan2
- CHPF | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV60535061; called by muse, mutect2
- COL12A1 | c.5032G>A p.G1678R | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV59397584; called by muse, mutect2, varscan2
- COL14A1 | c.2543C>T p.T848M | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as rs369592872; called by muse, mutect2, varscan2
- COL6A6 | c.2705C>A p.A902D | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.258); catalogued as rs377477478; called by muse, mutect2, varscan2
- COPB2 | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs1233418384, COSV60812816; called by muse, mutect2, varscan2
- CPS1 | c.2899C>A p.H967N | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV51812603; called by muse, mutect2, varscan2
- CRB1 | c.2293G>T p.V765F | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66330995; called by muse, mutect2, varscan2
- CRB2 | c.271G>A p.G91S | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs751212786, COSV63503639; called by muse, mutect2, varscan2
- CSMD1 | c.9040G>C p.G3014R (on ENST00000520002; = p.G3013R on NM_033225.6) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV59334006, COSV59364073; called by muse, mutect2, varscan2
- CTNNA2 | c.1532C>G p.S511C | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as rs762603105, COSV58151809, COSV58155968; called by muse, mutect2
- CYP7A1 | c.1018C>A p.L340M | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV56964035; called by muse, mutect2
- DCHS1 | c.6199C>T p.R2067C | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs368032944, COSV100202199; called by muse, mutect2, varscan2
- DCHS2 | n.4242G>T | Splice Region (SNP) | VAF 10/50 reads (20%) | catalogued as COSV61773191; called by muse, mutect2, varscan2
- DKK2 | c.709C>A p.L237M | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53394485, COSV53398448; called by muse, mutect2, varscan2
- DNAJC25 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57956978; called by muse, mutect2, varscan2
- DST | c.12232G>A p.D4078N (on ENST00000361203 / NM_001374722.1; = p.D1666N on NM_015548.5) | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as COSV55019298; called by muse, mutect2, varscan2
- E2F8 | c.1067G>T p.G356V | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV51464094; called by muse, mutect2
- ECPAS | c.4459G>C p.A1487P | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV52199274; called by muse, mutect2, varscan2
- ERBIN | c.2160C>G p.F720L | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs776790076, COSV52317952; called by muse, mutect2, varscan2
- EYA2 | c.1175A>T p.N392I | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV57944779; called by muse, mutect2, varscan2
- FAN1 | c.1130G>T p.R377L | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.441); catalogued as COSV100756025, COSV62951814; called by muse, varscan2
- FCER2 | c.21A>C p.S7= | Splice Region (SNP) | VAF 18/41 reads (44%) | catalogued as COSV60916586; called by muse, mutect2, varscan2
- FLT1 | c.637G>T p.G213W | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56729973; called by muse, mutect2, varscan2
- FRYL | c.3787C>T p.L1263F | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51949664; called by muse, mutect2
- GABRA1 | c.322A>G p.M108V | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV50106803, COSV99196293; called by muse, mutect2, varscan2
- GABRG3 | c.510G>C p.E170D | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.957); catalogued as COSV61520393; called by muse, mutect2, varscan2
- GALNT3 | c.410A>T p.E137V | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as COSV67061892; called by muse, mutect2, varscan2
- GBP3 | c.1060C>A p.L354M | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.482); catalogued as COSV52518782; called by muse, mutect2, varscan2
- GDF2 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782137039; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GFPT1 | c.916C>T p.R306C (on ENST00000357308 / NM_001244710.2; = p.R288C on NM_002056.4) | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.676); catalogued as COSV61948376; called by muse, mutect2, varscan2
- GFRAL | c.339C>G p.F113L | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61229406, COSV61231582; called by muse, mutect2, varscan2
- GPX1 | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs755209006, COSV69042637; called by muse, mutect2
- GRM7 | c.71T>A p.L24H | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.112); catalogued as COSV63146832; called by muse, mutect2
- H1-6 | c.494G>A p.R165K | Missense Mutation (SNP) | VAF 17/176 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs143795730; called by muse, mutect2, varscan2
- H2AC16 | c.53G>C p.R18P | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.867); catalogued as COSV58900278, COSV58900742; called by muse, mutect2, varscan2
- H3C3 | c.10A>G p.T4A | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV63551100; called by muse, mutect2, varscan2
- HDAC9 | c.1937G>T p.C646F | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67775021; called by muse, mutect2, varscan2
- HECW1 | c.2173G>A p.A725T | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.439); catalogued as rs1313411241, COSV67831345; called by muse, mutect2, varscan2
- HEG1 | c.799G>T p.E267* | Nonsense Mutation (SNP) | VAF 15/35 reads (43%) | catalogued as COSV60762888; called by muse, mutect2, varscan2
- HSPA13 | c.43C>T p.L15F | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV53465405; called by muse, mutect2, varscan2
- HYDIN | c.10352T>G p.L3451W | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66872481; called by muse, mutect2, varscan2
- IGFBP5 | c.565C>A p.Q189K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.258); catalogued as COSV52082831; called by muse, mutect2, varscan2
- IPO8 | c.2336G>T p.R779L | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV56242352; called by muse, mutect2, varscan2
- IQSEC3 | c.3157G>T p.G1053W | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as COSV58285866; called by muse, mutect2, varscan2
- ITIH5 | c.1382T>A p.V461E | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV53667670; called by muse, mutect2, varscan2
- ITK | c.1268G>T p.G423V | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV70062844; called by muse, mutect2, varscan2
- IWS1 | c.1165G>T p.V389L | Missense Mutation (SNP) | VAF 76/205 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.033); catalogued as COSV54869077; called by muse, mutect2, varscan2
- KASH5 | c.1461G>C p.Q487H | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as COSV71358053; called by muse, mutect2, varscan2
- KCNH1 | c.2392G>A p.V798I (on ENST00000271751 / NM_172362.3; = p.V771I on NM_002238.4) | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs761754626, COSV55085456; called by muse, mutect2
- KDM6B | c.3761A>G p.D1254G | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as COSV54682452; called by muse, mutect2, varscan2
- KIAA1755 | c.77C>A p.P26H | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54077210, COSV54080734; called by muse, mutect2, varscan2
- KIF1B | c.4305G>T p.S1435= (on ENST00000377086 / NM_001365952.1; = p.S1389= on NM_015074.3) | Splice Region (SNP) | VAF 8/37 reads (22%) | catalogued as COSV55809914; called by mutect2, varscan2
- KLB | c.376G>T p.G126C | Missense Mutation (SNP) | VAF 53/161 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.514); catalogued as COSV57302237; called by muse, mutect2, varscan2
- KRTAP10-7 | c.905G>T p.C302F | Missense Mutation (SNP) | VAF 37/178 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV59110787; called by muse, mutect2, varscan2
- KRTAP10-9 | c.854C>T p.S285F | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV59950861, COSV59965907; called by muse, mutect2, varscan2
- KRTAP5-3 | c.566G>T p.C189F | Missense Mutation (SNP) | VAF 118/366 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV68790757; called by muse, varscan2
- LAMA1 | c.6116C>G p.T2039R | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as COSV67538488; called by muse, mutect2, varscan2
- LAMB4 | c.122C>A p.T41K | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs140462508, COSV52721162; called by muse, mutect2, varscan2
- LCE1B | c.133A>G p.S45G | Missense Mutation (SNP) | VAF 31/249 reads (12%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs1399924556, COSV63980366; called by muse, mutect2, varscan2
- LHX8 | c.14G>C p.S5T | Missense Mutation (SNP) | VAF 16/89 reads (18%) | PolyPhen benign (0); catalogued as COSV53957264; called by muse, mutect2, varscan2
- LILRA2 | c.692G>T p.G231V | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52192502; called by muse, mutect2, varscan2
- LRP1B | c.6706A>G p.K2236E | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV67230213; called by muse, mutect2, varscan2
- LRRC30 | c.100C>G p.L34V | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV67301840, COSV67302602; called by muse, mutect2, varscan2
- LRRC32 | c.842C>A p.T281K | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV52633393; called by muse, mutect2, varscan2
- LRRC42 | c.725-1G>T p.X242_splice | Splice Site (SNP) | VAF 10/37 reads (27%) | catalogued as COSV59961038; called by muse, mutect2, varscan2
- MAGEB4 | c.78G>T p.K26N | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT tolerated (0.34); PolyPhen benign (0.034); catalogued as COSV64397219; called by muse, mutect2, varscan2
- MAP2 | c.3726G>C p.Q1242H | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.273); catalogued as COSV52293926; called by muse, mutect2, varscan2
- MC5R | c.8C>A p.S3Y | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.08); catalogued as COSV61254858; called by muse, mutect2, varscan2
- MCAM | c.1663C>T p.P555S | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as rs981978123, COSV50640175; called by muse, mutect2, varscan2
- MCAM | c.368C>A p.S123Y | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT tolerated (1); PolyPhen possibly damaging (0.811); catalogued as COSV50681113; called by muse, mutect2, varscan2
- ME3 | c.676G>A p.V226M | Missense Mutation (SNP) | VAF 61/113 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60165091; called by muse, mutect2, varscan2
- MED13L | c.1143G>T p.W381C | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99929485; called by muse, mutect2, varscan2
- MED13L | c.1142G>C p.W381S | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV99929487; called by muse, mutect2, varscan2
- MICU3 | c.729G>T p.M243I | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58846544; called by muse, mutect2, varscan2
- MUC16 | c.37078G>T p.G12360W | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.906); catalogued as COSV67471913; called by muse, mutect2, varscan2
- MYH4 | c.5668G>T p.E1890* | Nonsense Mutation (SNP) | VAF 13/60 reads (22%) | catalogued as COSV55117474, COSV55119542; called by muse, mutect2, varscan2
- MYLK3 | c.1007C>A p.S336Y | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV67364689; called by muse, varscan2
- MYO3B | c.2453G>A p.R818Q | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.788); catalogued as rs369549992; called by muse, mutect2, varscan2
- NAV3 | c.4934A>G p.Q1645R | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV57085060; called by muse, mutect2, varscan2
- NBAS | c.871G>T p.D291Y | Missense Mutation (SNP) | VAF 34/185 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV55724591; called by muse, mutect2, varscan2
- NCKAP5 | c.1330A>G p.S444G | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV58448760; called by muse, mutect2, varscan2
- NDST4 | c.1421A>G p.Q474R | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV52122536; called by muse, mutect2, varscan2
- NDUFA10 | c.861C>G p.D287E | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.209); catalogued as COSV53154777; called by muse, mutect2, varscan2
- NEUROG3 | c.346G>T p.D116Y | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs757577842, COSV54342620, COSV54343128; called by muse, mutect2, varscan2
- NLRP14 | c.1793C>A p.A598E | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as COSV55067906, COSV55069606; called by muse, mutect2, varscan2
- NLRP4 | c.677T>C p.L226P | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56715429; called by muse, mutect2, varscan2
- NPAP1 | c.1987A>T p.S663C | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.123); catalogued as COSV61507779; called by muse, mutect2, varscan2
- NUDT8 | c.327G>A p.P109= | Splice Region (SNP) | VAF 19/76 reads (25%) | catalogued as rs749779116, COSV56875821; called by muse, mutect2, varscan2
- NXPE1 | c.1123G>C p.D375H (on ENST00000424269; = p.D233H on NM_152315.5) | Missense Mutation (SNP) | VAF 23/32 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1222898580, COSV52630040, COSV52630810; called by muse, mutect2, varscan2
- NYAP1 | c.265G>A p.G89S | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55719402; called by muse, mutect2, varscan2
- OR1N2 | c.793C>A p.P265T | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as COSV65460309, COSV65460395; called by muse, mutect2, varscan2
- OR1N2 | c.794C>A p.P265H | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV101031434; called by muse, mutect2, varscan2
- OR2A25 | c.148C>A p.L50M | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.621); catalogued as COSV68717301; called by muse, mutect2
- OR2B2 | c.583A>C p.N195H | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV57579266; called by muse, mutect2, varscan2
- OR51A2 | c.902G>T p.R301I | Missense Mutation (SNP) | VAF 55/85 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV66748482; called by muse, mutect2, varscan2
- OR51A4 | c.514A>T p.K172* | Nonsense Mutation (SNP) | VAF 24/254 reads (9%) | catalogued as COSV66749575; called by muse, mutect2
- OR52E6 | c.662G>T p.R221M | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.774); catalogued as COSV61432323; called by muse, mutect2, varscan2
- OR52N4 | c.374A>G p.Y125C | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as rs1050111761, COSV57891386; called by muse, mutect2, varscan2
- OR5D16 | c.844G>T p.V282L | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.442); catalogued as rs375193534, COSV101004143, COSV65721854; called by muse, mutect2, varscan2
- OR8G5 | c.807C>A p.D269E | Missense Mutation (SNP) | VAF 72/138 reads (52%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.043); catalogued as COSV100422546; called by muse, mutect2, varscan2
- PIFO | c.472G>C p.V158L | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.243); catalogued as COSV63863924; called by muse, mutect2, varscan2
- PKP1 | c.1472C>A p.P491H | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55822024; called by muse, mutect2, varscan2
- PLCG2 | c.2659G>T p.E887* | Nonsense Mutation (SNP) | VAF 16/76 reads (21%) | catalogued as COSV63870674; called by muse, mutect2, varscan2
- PLCXD3 | c.762C>A p.S254R | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.944); catalogued as rs367634633; called by muse, mutect2, varscan2
- PLEKHG2 | c.3638C>G p.P1213R | Missense Mutation (SNP) | VAF 18/308 reads (6%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.372); catalogued as rs1266871522, COSV52684982; called by muse, mutect2
- PLXND1 | c.1678G>T p.G560C | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV60714668; called by muse, mutect2, varscan2
- PMS1 | c.70G>A p.V24I | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs553130827, COSV100575727; called by muse, mutect2, varscan2
- POLQ | c.2702G>T p.C901F | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV51753689; called by muse, mutect2, varscan2
- POU4F2 | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.105); catalogued as rs1217405055, COSV55584880; called by muse, mutect2, varscan2
- PRR16 | c.227A>T p.K76I (on ENST00000407149 / NM_001300783.2; = p.K53I on NM_016644.2) | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV65400609; called by muse, mutect2, varscan2
- PTGFR | c.955G>T p.A319S | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.049); catalogued as COSV66115236; called by muse, mutect2, varscan2
- PTPN5 | c.521C>A p.T174N | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.01); catalogued as COSV62126472; called by muse, mutect2, varscan2
- PTPRT | c.2206G>A p.E736K | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61987152; called by muse, mutect2, varscan2
- PWWP3A | c.272C>T p.S91L (on ENST00000627377; = p.S90L on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV60902626; called by muse, mutect2, varscan2
- RASSF9 | c.538C>G p.R180G | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.272); catalogued as rs1309588415, COSV63434163, COSV63435081; called by muse, mutect2, varscan2
- RHOXF1 | c.349G>T p.E117* | Nonsense Mutation (SNP) | VAF 55/81 reads (68%) | catalogued as COSV54294830; called by muse, mutect2, varscan2
- RNF157 | c.506A>T p.Q169L | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV53944851; called by muse, mutect2, varscan2
- RREB1 | c.1483G>T p.A495S | Missense Mutation (SNP) | VAF 31/640 reads (5%) | SIFT tolerated (0.89); PolyPhen benign (0.025); catalogued as COSV58559209; called by muse, mutect2
- RUNX1T1 | c.384G>T p.R128S (on ENST00000265814 / NM_001198628.1; = p.R101S on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV56149591; called by muse, mutect2, varscan2
- RYR2 | c.14864G>T p.G4955V | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM1410656, COSV63667506, COSV63684999; called by muse, mutect2, varscan2
- SCGB1D4 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.754); catalogued as COSV100669543, COSV62204104; called by muse, mutect2, varscan2
- SCN2A | c.1661C>T p.S554F | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.945); catalogued as rs764865753, COSV51844172; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN3A | c.1609T>A p.F537I | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.142); catalogued as COSV51812348; called by muse, mutect2, varscan2
- SERINC2 | c.488G>C p.G163A (on ENST00000373709 / NM_178865.5; = p.G167A on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/161 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV65490654, COSV65491609; called by muse, mutect2, varscan2
- SIPA1L2 | c.5099C>A p.S1700Y | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53391910; called by muse, mutect2
- SLC13A3 | c.1360G>T p.G454W | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51717060; called by muse, mutect2, varscan2
- SLC22A4 | c.82A>G p.S28G | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as COSV52358524; called by muse, mutect2, varscan2
- SLC39A12 | c.334C>G p.Q112E | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.043); catalogued as COSV66198990, COSV66200255; called by muse, mutect2, varscan2
- SLC45A2 | c.672G>T p.L224F | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.088); catalogued as COSV56872477; called by muse, mutect2, varscan2
- SLC4A1 | c.766G>T p.V256L | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV52260613; called by muse, mutect2, varscan2
- SLC4A10 | c.758A>C p.D253A | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV55782518; called by muse, mutect2, varscan2
- SLC8A1 | c.1552C>T p.L518F | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.023); catalogued as rs879109970, COSV60483141; called by muse, mutect2, varscan2
- SLITRK2 | c.2197C>A p.P733T | Missense Mutation (SNP) | VAF 56/97 reads (58%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV59425995; called by muse, mutect2, varscan2
- SOCS6 | c.595G>T p.G199* | Nonsense Mutation (SNP) | VAF 16/112 reads (14%) | catalogued as COSV67546548; called by muse, mutect2, varscan2
- SPO11 | c.227C>G p.S76* | Nonsense Mutation (SNP) | VAF 27/168 reads (16%) | catalogued as COSV61995954; called by muse, mutect2, varscan2
- SSH2 | c.3151A>T p.T1051S | Missense Mutation (SNP) | VAF 58/109 reads (53%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.039); catalogued as COSV52173675; called by muse, mutect2, varscan2
- STAT5B | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.562); catalogued as COSV53183487; called by muse, mutect2, varscan2
- SYT7 | c.248C>G p.A83G | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.099); catalogued as COSV55656367; called by muse, mutect2, varscan2
- TBC1D2 | c.1981G>A p.A661T | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV59785534; called by muse, mutect2, varscan2
- TBX15 | c.1243G>T p.G415W (on ENST00000369429 / NM_001330677.2; = p.G309W on NM_152380.3) | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.924); catalogued as COSV52871996; called by muse, mutect2, varscan2
- TBX18 | c.1004+2T>G p.X335_splice | Splice Site (SNP) | VAF 14/18 reads (78%) | catalogued as COSV63737091; called by muse, varscan2
- TCF12 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.438); catalogued as COSV51008609; called by muse, mutect2
- TENM2 | c.6758G>T p.R2253L (on ENST00000518659 / NM_001122679.2; = p.R2014L on NM_001080428.3) | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69126892, COSV69132347; called by muse, mutect2, varscan2
- TMEM130 | c.241C>T p.L81F | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59559537; called by muse, mutect2, varscan2
- TMEM214 | c.1138G>C p.E380Q | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.322); catalogued as COSV53192920, COSV99476307; called by muse, mutect2, varscan2
- TNFAIP2 | c.1891C>T p.R631W | Missense Mutation (SNP) | VAF 21/359 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs774873377, COSV60694033; called by muse, mutect2
- TNFRSF4 | c.518C>G p.A173G | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.594); catalogued as COSV55419664; called by muse, mutect2, varscan2
- TRPC4 | c.1472G>A p.R491H | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV59002713; called by muse, mutect2, varscan2
- TRPM2 | c.2684G>T p.G895V | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV55970938; called by muse, mutect2, varscan2
- TSGA10IP | c.1267G>A p.A423T | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV73245313; called by muse, mutect2, varscan2
- TTN | c.12775A>G p.K4259E (on ENST00000591111; = p.K4213E on NM_003319.4) | Missense Mutation (SNP) | VAF 17/88 reads (19%) | catalogued as COSV60113838; called by muse, mutect2, varscan2
- UBXN7 | c.86G>A p.S29N | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.027); catalogued as rs1396450451, COSV56355927; called by muse, mutect2, varscan2
- USH2A | c.14914C>A p.R4972S | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.87); catalogued as CM149194, COSV56368139, COSV56381263; called by muse, mutect2, varscan2
- UTP6 | c.1240A>G p.I414V | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as COSV55573717; called by muse, mutect2, varscan2
- VEPH1 | c.1964A>T p.H655L | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV62879468; called by muse, mutect2
- WDR64 | c.1281G>C p.M427I | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.021); catalogued as COSV63796701; called by muse, mutect2, varscan2
- WDR64 | c.1354C>A p.H452N | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as COSV63796705; called by mutect2, varscan2
- WDR64 | c.1462C>A p.L488I | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV100843728, COSV63796712; called by muse, mutect2, varscan2
- WSCD2 | c.1309A>G p.I437V | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs746343728, COSV54584044; called by muse, mutect2, varscan2
- XIRP2 | c.3253T>A p.C1085S (on ENST00000628543; = p.C1260S on NM_152381.6) | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV54706372; called by muse, mutect2, varscan2
- XIRP2 | c.3973G>A p.D1325N (on ENST00000628543; = p.D1500N on NM_152381.6) | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs958465056, COSV54706385; called by muse, mutect2, varscan2
- ZCCHC14 | c.50G>T p.R17L (on ENST00000268616; = p.R154L on NM_015144.3) | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.308); catalogued as COSV51886864; called by muse, mutect2
- ZFHX4 | c.2053A>T p.R685W | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50973918; called by muse, mutect2
- ZNF133 | c.859A>G p.I287V (on ENST00000316358 / NM_001352454.2; = p.I286V on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.261); catalogued as COSV60367246; called by muse, mutect2, varscan2
- ZNF366 | c.500C>A p.T167N | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.014); catalogued as COSV59216148; called by muse, mutect2, varscan2
- ZNF454 | c.1274C>G p.S425* | Nonsense Mutation (SNP) | VAF 9/36 reads (25%) | catalogued as COSV60768758; called by muse, mutect2, varscan2
- ZNF467 | c.1006G>T p.A336S | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.033); catalogued as COSV57373498; called by muse, mutect2, varscan2
- ZNF521 | c.978C>A p.Y326* | Nonsense Mutation (SNP) | VAF 11/65 reads (17%) | catalogued as COSV64127856; called by muse, mutect2, varscan2
- ZSWIM1 | c.192G>T p.Q64H | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54848262; called by muse, mutect2, varscan2
- ZSWIM2 | c.1867del p.E623Sfs*4 | Frame Shift Del (DEL) | VAF 7/33 reads (21%) | catalogued as COSV99719842; called by mutect2, pindel, varscan2
- FER1L6 | c.97del p.A33Hfs*38 | Frame Shift Del (DEL) | VAF 14/122 reads (11%) | called by mutect2, pindel, varscan2
- IGHV1-58 | c.107C>A p.S36* | Nonsense Mutation (SNP) | VAF 31/96 reads (32%) | called by muse, mutect2, varscan2
- IGKV1-9 | c.12G>T p.R4S | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- RHCG | c.554dup p.H185Qfs*114 | Frame Shift Ins (INS) | VAF 19/120 reads (16%) | called by mutect2, pindel, varscan2
- RNF213 | c.2845del p.A949Rfs*39 | Frame Shift Del (DEL) | VAF 14/74 reads (19%) | called by mutect2, pindel, varscan2
- SEC24C | c.24dup p.P9Tfs*167 | Frame Shift Ins (INS) | VAF 14/86 reads (16%) | called by mutect2, pindel, varscan2
- TPTE | c.1133A>T p.H378L (on ENST00000618007 / NM_199261.4; = p.H360L on NM_199259.4) | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- XIRP2 | c.8239_8240del p.Q2747Efs*15 (on ENST00000628543; = p.Q2922Efs*15 on NM_152381.6) | Frame Shift Del (DEL) | VAF 8/62 reads (13%) | called by pindel, varscan2
- ZNF511 | c.678_679dup p.R227Ifs*9 (on ENST00000359035; = p.R227Ifs*76 on NM_145806.4) | Frame Shift Ins (INS) | VAF 25/132 reads (19%) | called by mutect2, pindel, varscan2
- ACAA2 | c.852A>T p.V284= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as COSV53271051; called by muse, mutect2, varscan2
- CACNA1I | c.120G>A p.E40= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as rs755012678, COSV60810574, COSV60815076; called by muse, mutect2, varscan2
- CBX2 | c.579G>T p.L193= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as COSV53969307; called by muse, mutect2, varscan2
- CCL25 | c.156G>A p.Q52= | Silent (SNP) | VAF 33/53 reads (62%) | catalogued as rs369217231; called by muse, mutect2, varscan2
- COBL | c.453T>C p.P151= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV54347968; called by muse, mutect2, varscan2
- COL9A3 | c.366C>A p.P122= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV59653442; called by mutect2, varscan2
- CPA6 | c.348G>T p.L116= | Silent (SNP) | VAF 29/280 reads (10%) | catalogued as COSV52731718; called by muse, mutect2, varscan2
- DYDC1 | c.297G>A p.R99= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as rs777842474, COSV64722962; called by muse, mutect2, varscan2
- FAM131B | c.804G>T p.L268= | Silent (SNP) | VAF 25/203 reads (12%) | catalogued as COSV58370645; called by muse, mutect2, varscan2
- FAN1 | c.1131G>T p.R377= | Silent (SNP) | VAF 24/118 reads (20%) | catalogued as COSV100756028; called by muse, varscan2
- GRHL2 | c.468G>T p.T156= | Silent (SNP) | VAF 81/160 reads (51%) | catalogued as COSV52549519; called by muse, mutect2, varscan2
- ITGA9 | c.195G>T p.V65= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV53244371; called by muse, varscan2
- ITGB1 | c.453G>T p.L151= | Silent (SNP) | VAF 16/119 reads (13%) | catalogued as COSV56482699; called by muse, mutect2, varscan2
- LCT | c.1992C>G p.P664= | Silent (SNP) | VAF 33/97 reads (34%) | catalogued as COSV51545753, COSV51550998; called by muse, mutect2, varscan2
- LILRB1 | c.1530G>T p.G510= (on ENST00000427581; = p.G460= on NM_006669.6) | Silent (SNP) | VAF 24/48 reads (50%) | catalogued as COSV61118814; called by muse, mutect2, varscan2
- MROH9 | c.363A>C p.L121= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV63011859; called by muse, mutect2, varscan2
- MYH13 | c.270C>T p.D90= | Silent (SNP) | VAF 37/147 reads (25%) | catalogued as COSV52831198; called by muse, mutect2, varscan2
- NEUROG3 | c.132G>A p.G44= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as rs758061188, COSV54343140; called by muse, mutect2, varscan2
- NFASC | c.1989C>T p.V663= (on ENST00000339876 / NM_001378329.1; = p.V659= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 41/115 reads (36%) | catalogued as COSV58367394, COSV58370958; called by muse, mutect2, varscan2
- NFATC3 | c.981A>T p.P327= | Silent (SNP) | VAF 18/115 reads (16%) | catalogued as COSV60474628; called by muse, mutect2, varscan2
- NOVA1 | c.1137G>T p.T379= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV57478512; called by muse, varscan2
- NTM | c.243G>A p.K81= | Silent (SNP) | VAF 43/87 reads (49%) | catalogued as rs753412480, COSV66181970; called by muse, mutect2, varscan2
- OPTC | c.783T>C p.S261= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV65867930; called by muse, mutect2, varscan2
- OR1K1 | c.513T>G p.A171= | Silent (SNP) | VAF 32/102 reads (31%) | catalogued as COSV52956656; called by muse, mutect2, varscan2
- OR2C3 | c.249G>T p.L83= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV63575216; called by muse, mutect2, varscan2
- OR2V2 | c.723C>T p.T241= | Silent (SNP) | VAF 15/98 reads (15%) | catalogued as COSV100080039, COSV60315728; called by muse, mutect2, varscan2
- OR8D2 | c.828G>A p.V276= | Silent (SNP) | VAF 18/127 reads (14%) | catalogued as COSV62488582; called by muse, mutect2, varscan2
- OR8K1 | c.375C>A p.A125= | Silent (SNP) | VAF 47/171 reads (27%) | catalogued as COSV54401639; called by muse, mutect2, varscan2
- PABPN1 | c.582C>G p.G194= | Silent (SNP) | VAF 12/114 reads (11%) | catalogued as rs150035782; called by muse, mutect2, varscan2
- PCDH11X | c.3858T>A p.A1286= | Silent (SNP) | VAF 61/191 reads (32%) | catalogued as COSV100007577, COSV53472980; called by muse, mutect2, varscan2
- PLAGL2 | c.459C>T p.S153= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as rs763119089, COSV55788590; called by mutect2, varscan2
- PRDM9 | c.1032C>T p.C344= | Silent (SNP) | VAF 55/128 reads (43%) | catalogued as COSV57002476, COSV57007467; called by muse, mutect2, varscan2
- PTCHD3 | c.967C>A p.R323= | Silent (SNP) | VAF 61/185 reads (33%) | catalogued as COSV71256401, COSV71256933; called by muse, mutect2, varscan2
- RAB31 | c.174C>A p.L58= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV71261748; called by muse, mutect2, varscan2
- RAB3GAP1 | c.1551A>T p.L517= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV51483329; called by muse, mutect2, varscan2
- RYR3 | c.6849A>T p.A2283= (on ENST00000389232; = p.A2284= on NM_001036.6) | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as COSV63109688; called by muse, mutect2, varscan2
- SAMD14 | c.1242C>A p.A414= (on ENST00000330175 / NM_001257359.2; = p.A442= on NM_174920.4) | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as COSV50303850; called by muse, mutect2, varscan2
- SLITRK2 | c.180C>A p.P60= | Silent (SNP) | VAF 24/32 reads (75%) | catalogued as rs782190139, COSV59425987; called by muse, mutect2, varscan2
- SLITRK5 | c.258C>T p.L86= | Silent (SNP) | VAF 31/117 reads (26%) | catalogued as rs373342343, COSV100280455; called by muse, mutect2, varscan2
- STK11 | c.579C>A p.S193= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as rs730881961, COSV100480705, COSV58824759; ClinVar: likely benign; called by muse, mutect2, varscan2
- TACC2 | c.7503G>C p.L2501= (on ENST00000334433; = p.L579= on NM_006997.4) | Silent (SNP) | VAF 26/114 reads (23%) | catalogued as COSV53282493; called by muse, mutect2, varscan2
- TAS1R2 | c.30C>T p.S10= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as rs755320101, COSV64745376; called by muse, mutect2, varscan2
- TIFAB | c.21C>A p.V7= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as COSV72345838; called by muse, mutect2, varscan2
- TRIM42 | c.918C>T p.N306= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as rs756297389, COSV53883708; called by muse, mutect2, varscan2
- TRPV4 | c.2397G>T p.P799= | Silent (SNP) | VAF 40/126 reads (32%) | catalogued as COSV55682740; called by muse, mutect2, varscan2
- USP36 | c.348G>T p.R116= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV61752007; called by muse, mutect2, varscan2
- VTN | c.808C>A p.R270= | Silent (SNP) | VAF 58/121 reads (48%) | catalogued as rs781794064, COSV56872456, COSV56873809; called by muse, mutect2, varscan2
- WFIKKN2 | c.456C>A p.T152= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV60959028; called by muse, varscan2
- WRN | c.636T>C p.Y212= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV53301339; called by muse, mutect2, varscan2
- ZBTB16 | c.1008G>C p.V336= | Silent (SNP) | VAF 35/72 reads (49%) | catalogued as COSV60094089; called by muse, mutect2, varscan2
- ZNF12 | c.762G>A p.S254= (on ENST00000405858 / NM_016265.4; = p.S216= on NM_006956.3) | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as rs372158854; called by muse, mutect2, varscan2
- ZNF598 | c.1500C>T p.P500= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs761860084, COSV70910771; called by muse, mutect2
- ARHGEF11 | c.583-1774G>A | Intron (SNP) | VAF 15/46 reads (33%) | catalogued as COSV63816409; called by muse, mutect2, varscan2
- MORF4 | n.688G>T | RNA (SNP) | VAF 46/192 reads (24%) | called by muse, mutect2, varscan2
- OBSCN | c.11659+4997G>T | Intron (SNP) | VAF 12/113 reads (11%) | catalogued as COSV99481788; called by muse, mutect2, varscan2
- OSGIN1 | n.1472G>T | RNA (SNP) | VAF 10/58 reads (17%) | catalogued as COSV59421057; called by muse, mutect2, varscan2
